Surgical pathology report (de-identified scan), TCGA case TCGA-24-1920, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1920-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

OVARY, RIGHT, BILATERAL SEPTAL OOPHORECTOMY

- HIGH GRADE SEROUS ADENOCARCINOMA
- SEE COMMENT AND SYNOPSIS

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- SURFACE IMPLANTS OF METASTATIC SEROUS ADENOCARCINOMA

FALLOPIAN TUBES, BILATERAL, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE PATTERN

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMA

UTERUS, SEROSAL SURFACE, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, "RIGHT PARAMETRIA," BIOPSY

- METASTATIC SEROUS ADENOCARCINOMA
- NO EVIDENCE OF MALIGNANCY IN ONE INCIDENTAL LYMPH NODE

LYMPH NODES, RIGHT PELVIC, EXCISION

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES

OMENTUM, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[page 2 of 4]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

***Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen area is a 'right tube and ovary,' consisting of a 43 gram that measures 6 x 5.5 x 2 cm portion of a tan-brown tumor, putative portion of fallopian tube that measures 4.5 x 0.8 cm. Two areas frozen as FS1. Tissue taken for [REDACTED] protocol. Rest for permanents," by [REDACTED]

FS1: Ovary, right, excision

- "Adenocarcinoma, favor Mullerian," by [REDACTED]

Microscopic Description and Comment:

Sections of the right ovary show a high grade müllerian adenocarcinoma. The majority of the tumor (over 95%) is high grade serous adenocarcinoma, although focal areas of clear cell adenocarcinoma, and endometrioid adenocarcinoma with squamous differentiation, are present. [REDACTED]

History:

The patient is a [REDACTED] with a history of breast carcinoma [REDACTED] who has an elevated CA125, pelvic mass, and ascites. Operative procedure: Examination under anesthesia with exploratory laparotomy with total abdominal hysterectomy with bilateral salpingo-oophorectomy with omentectomy.

Specimen(s) Received:

A: RIGHT OVARY AND RIGHT FALLOPIAN TUBE
B: UTERUS, CERVIX, LEFT FALLOPIAN TUBE AND LEFT OVARY
C: RIGHT PARAMETERIA
D: LYMPH NODES, RIGHT PELVIC
E: OMENTUM

Gross Description:

The specimens are received in five formalin-filled containers, each labeled [REDACTED]. The first container is labeled "right tube and ovary, FS1/X." It holds a 43 gram previously sectioned right ovary that measures 6 x 5.5 x 2 cm. Sectioning shows a tan-brown, necrotic tumor with multiple hemorrhagic areas, the largest measuring 2 x 1 cm. There is a putative normal ovarian parenchyma that measures 1 x 1 cm. This 4.5 x 0.8 x 0.3 cm putative fallopian tube has a tan-brown outer surface. Cut section shows a putative lumen. Also in the container is a white cassette designated FS1 that holds multiple fragments of tan soft tissue that measures 2.5 x 2.5 x 0.2 cm. Labeled A1 (FS1); A2 to A5 - section of tan-brown tumor; A6 - putative normal ovarian parenchyma; A7 - putative fallopian tube. [REDACTED]

The second container is labeled "uterus, cervix, left tube and ovary." It holds a uterus with attached cervix and left adnexa that together weigh 56 g. The uterus with attached cervix measures 7.5 cm from fundus to ectocervix, 3 cm from cornu to cornu, and 2.8 cm from anterior to posterior. The serosal surface is pink-tan, glistening, and shiny with multiple exudative areas, the largest on the anterior surface measuring 2.5 x 1 cm. The serosal surface at the posterior aspect shows a tan-brown nodule that measures 1 x 1 cm. The 3 x 3.2 x 2.2 cm cervix has a 2.5 x 2.6 cm, beige, glistening, shiny ectocervix and a 0.5 cm external os. The 2.5 x 0.5 cm endocervical canal is pink-tan. The 2.5 x 1 cm endometrial cavity is pink-tan. Sections show maximum endometrial thickness of 0.1 cm and a maximum myometrial thickness is 1.2 cm. The 1.8 x 1 x 1 cm, tan-brown left ovary has a tan-brown cut surface. The 5 x 1 x 1 cm fallopian tube has a tan-brown nodular outer surface; sections show a pinpoint lumen. Labeled B1, B2 - anterior posterior cervix; B3, B4 - anterior posterior lower uterine segment; B5, B6 - anterior posterior endomyometrium; B7 - firm calcified nodule at the serosal aspect of the uterus; B8 - tan exudative area at the serosal aspect of the uterus; B9 to B18 - left ovary with fallopian tube from medial to lateral (entirely submitted). [REDACTED]

[page 3 of 4]
The third container is labeled "right parametrium." It holds multiple fragments of tan-brown soft tissue measuring 6 x 5 x 0.3 cm in aggregate. [REDACTED]

The fourth container is labeled "right pelvic lymph nodes." It holds multiple fragments of adipose tissue measures 4 x 3 x 0.2 cm in aggregate. Multiple putative lymph nodes are extracted, the largest measuring 1.5 x 1 x 0.2 cm; the smallest, 0.3 x 0.5 x 0.2 cm. [REDACTED]

The fifth container is labeled "omentum." It holds multiple fragments of firm soft omentum that measures 20 x 15 x 4 cm. Sectioning shows a 17 x 11 x 3 cm nodular firm and necrotic area. Labeled E1, E2 - omentum. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

High grade serous carcinoma

TUMOR LOCATION

The location of the primary tumor is the right ovary only

HISTOLOGIC GRADE

The histologic grade is poorly differentiated [REDACTED]

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR [REDACTED]

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as no regional lymph node metastasis (N0)

The total number of regional lymph nodes examined is 5

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

T3c/N0/MX (Stage X)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file fac9accf-e2ca-4ce7-bf63-0ed1ecde6424 (TCGA-24-1920.292D7FE5-E949-458B-B7DA-CC55009B1C06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).